Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GU-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

1CD-0-3

Melanoma, Nos 8720/3

Site: lymph node, groin C77.4

lw 6/10/11

CLINICAL DETAILS

(R) inguinal metastasis from 0.3mm and (R) calf.
(R) ileo-inguinal node dissection. Histopath.
Long stitch = distal. Loop stitch = proximal.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking- area marked blue.
Pathologist:

(Registrar/

MACROSCOPIC DESCRIPTION

(Dt

Two specimens were received.

1. "RIGHT GROIN DISSECTION LONG DISTAL LOOP PROXIMAL".

A piece of fibrofatty tissue measuring 297 x 78 x 50mm. There are two sutures one is long and allocates distal, the other one has a loop shape and allocates proximal. There is an area inked blue, it appears the tissue has been taken from that area for tumour banking. Dissection has been undertaken from distal to opposite end. There is an attached skin ellipse measuring 53 x 8mm. The skin ellipse appears macroscopically unremarkable. The previously discussed nodule which has been banked for tumour banking measures 37 x 28 x 28mm. It appears partially pale, partially haemorrhagic and necrotic. Representative sections embedded in blocks A - B.

- A-B. Large Lymph node (tumour banked).
- C. One bisected lymph node.
- D. One bisected lymph node.
- E. One bisected lymph node.
- F. Five lymph nodes.
- G. Two lymph nodes.
- H. One bisected lymph node.
- J. One dissected lymph node.
- K. One bisected aggregate of two lymph nodes.

2. "RIGHT GROIN DISSECTION". The specimen consists of multiple pieces of fibrofatty tissue measuring 70 x 60 x 35mm.

- A. Three lymph node.
- B. One bisected lymph node.
- C. One bisected lymph node.
- D. Three possible lymph nodes.
- E-F. One dissected lymph node.

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

G-H. One trisected lymph node.

MICROSCOPIC REPORT

1. One of thirteen lymph nodes show involvement by metastatic malignant melanoma. The largest node is almost replaced by tumour. The cells are epithelioid with prominent nucleoli. Pigment is not seen. There is no extranodal spread. The tumour is positive for S100, HMB45 and Melan A.
2. A total of eleven lymph nodes show no evidence of malignancy.

SUMMARY

1. RIGHT GROIN DISSECTION - malignant melanoma 1/13 nodes.
/
2. RIGHT GROIN DISSECTION - no evidence of malignancy.

REPORTED BY: Dr. .

Source: NCI Genomic Data Commons file b132beed-b420-467b-a073-ee3c7b45ec31 (TCGA-EE-A2GU.83D3B219-4C20-405C-B432-A6948F54E97E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).